TCGA case TCGA-DX-A3LU — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e786de34-4c21-460f-89ab-008de4347049

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (4)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 60.0 years (21,915 days); Year of diagnosis: 2007; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 14; Tumor length measurement: 19; Tumor width measurement: 16.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 10.5; Tumor length measurement: 16.5; Tumor width measurement: 15.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 60.8 years (22,205 days); Days to diagnosis: 290 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 19.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 14; Tumor width measurement: 11.5.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 64.7 years (23,631 days); Days to diagnosis: 1,716 days (4.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.4; Tumor width measurement: 7.2.
4. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 66.8 years (24,395 days); Days to diagnosis: 2,480 days (6.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.4; Tumor width measurement: 6.7.

Follow-up (5 entries)
- Day 290 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 290 days; Discontiguous lesion count: 2.
- Day 1,716 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 1,716 days (4.7 years).
- Days to follow up: 2,144 days (5.9 years); Disease response: With Tumor.
- Day 2,480 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 2,480 days (6.8 years).
- Days to follow up: 2,641 days (7.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3LU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-DX-A3LU-01A-01-TSA: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3LU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3LU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Positive; Disease multifocal indicator: No; Well diff liposarc prior diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 451; Days from index date to pharmaceutical treatment ended: 492; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 451; Days from index date to pharmaceutical treatment ended: 492; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1974; Days from index date to pharmaceutical treatment ended: 2200; Pharmaceutical therapy drug name: PD 0332991; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,641 days; disease-specific survival: no event (censored), 2,641 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 290 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3LU-01A-11D-A21P-01): tumor purity 0.42, ploidy 2.09, whole-genome doublings 0.
